Somatic mutation profile of tumor specimen ALCH-AE0U-TTP1-B (aliquot ALCH-AE0U-TTP1-B-1-0-D-A627-36) from ALCHEMIST case ALCH-AE0U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.8 years (20,746 days).
Specimen ALCH-AE0U-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68f246d3-57ed-4a91-89bc-7197ccc231db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0U-NB1-A (Blood Derived Normal), aliquot ALCH-AE0U-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e82b1fa-5f09-4547-b096-e222463e1089

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 6, Silent 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 69/456 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AL121899.2 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs190943274; called by muse, mutect2, varscan2
- ERN1 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1280433194; called by muse, varscan2
- IGHV1-69 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 131/315 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs377032763; called by muse, mutect2, varscan2
- LRP2 | c.3962G>T p.G1321V | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55553114; called by muse, mutect2, varscan2
- WRNIP1 | c.287_292del p.G96_E97del | In Frame Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs754408999; called by mutect2, pindel
- CDH19 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- HEBP2 | c.165dup p.M56Yfs*46 | Frame Shift Ins (INS) | VAF 74/407 reads (18%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.6238C>T p.H2080Y | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- PAPPA | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.025); called by muse, mutect2
- SMTNL1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBR1 | c.1386+1G>A p.X462_splice | Splice Site (SNP) | VAF 50/425 reads (12%) | called by muse, mutect2, varscan2
- BCL11B | c.1725G>A p.G575= (on ENST00000357195 / NM_001282237.2; = p.G504= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/164 reads (30%) | called by muse, mutect2, varscan2
- OR2L5 | c.396C>G p.P132= | Silent (SNP) | VAF 79/720 reads (11%) | catalogued as rs780637487; called by muse, mutect2, varscan2
- DGCR2 | c.1006+1698G>A | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- JADE2 | c.1552+115G>T | Intron (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- LRCH3 | c.2209-2965C>T | Intron (SNP) | VAF 58/646 reads (9%) | catalogued as rs1430962461; called by muse, mutect2
- MPP4 | c.1052-158T>C | Intron (SNP) | VAF 27/246 reads (11%) | catalogued as rs1196493766; called by muse, mutect2, varscan2
- MYO9A | c.5142+612C>T | Intron (SNP) | VAF 45/314 reads (14%) | catalogued as rs749889674; called by muse, mutect2, varscan2
- ZNF446 | c.713-73G>A | Intron (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
